Gene-level copy-number profile of tumor specimen TARGET-40-PASRNE-01A from TARGET case TARGET-40-PASRNE, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 3.6 years (1,299 days).
Specimen TARGET-40-PASRNE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.5aad5584-3b16-50f2-9990-5d4487600493.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PASRNE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 373 have no estimate.
https://portal.gdc.cancer.gov/files/9ceeb93e-330e-4313-ae52-d886c44d97a6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 537; copy number 1: 231; copy number 2: 15,420; copy number 3: 13,913; copy number 4: 24,155; copy number 5: 1,364; copy number 6: 1,351; copy number 7: 527; copy number 8: 699; copy number 9: 161; copy number 10: 246; copy number 11: 285; copy number 12: 113; copy number 13: 457; copy number 14: 152; copy number 15: 220; copy number 16: 33; copy number 17: 24; copy number 18: 30; copy number 19: 13; copy number 20: 11; copy number 21: 90; copy number 23: 33; copy number 24: 90; copy number 25: 29; copy number 26: 16; copy number 27: 14; copy number 28: 8; copy number 32: 28.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:115,802,363–117,139,389, 1 gene (within-gene range 0–2): LSAMP.
- chr3:116,552,473–117,027,039, 10 genes: LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr8:39,309,909–39,522,852, 3 genes: AC105185.1, ADAM5, ADAM3A.
- chr12:9,448,295–9,658,392, 3 genes (within-gene range 0–4): AC092821.3, AC092821.1, AC092821.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,053 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:91,260,766–91,404,856, 1 gene, copy number 9 (within-gene range 6–9): HFM1.
- chr1:91,328,369–91,906,335, 7 genes, copy number 9: FEN1P1, CDC7, WDR82P2, AL714022.1, HSP90B3P, TGFBR3, RN7SL653P.
- chr2:88,811,186–88,861,563, 1 gene, copy number 13 (within-gene range 4–13): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 13: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr3:141,228,726–141,367,753, 2 genes, copy number 24 (within-gene range 4–24): PXYLP1, AC022215.2.
- chr3:141,267,353–150,244,232, 148 genes, copy number 12–26 (within-gene range 2–26) (broad region; genes not listed).
- chr4:11,625,714–12,641,009, 7 genes, copy number 17–18: AC005699.1, LINC02360, AC108037.1, LINC02270, RNU6-578P, ECM1P2, AC093809.1.
- chr4:33,010,948–34,966,344, 14 genes, copy number 15–19: MAPRE1P2, AC093606.1, AC093878.1, AC097535.2, AC097535.1, AC079772.1, AC016687.3, AC016687.2, AC016687.1, LINC02484, AC110790.1, AC093689.1, AC093913.1, AC020589.1.
- chr4:53,377,839–54,295,272, 2 genes, copy number 11 (within-gene range 6–11): AC058822.1, LNX1.
- chr4:53,575,713–56,328,625, 54 genes, copy number 11 (within-gene range 6–11): AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161.
- chr4:56,291,601–56,299,873, 1 gene, copy number 10: AC022267.1.
- chr4:59,047,020–59,630,324, 5 genes, copy number 9: AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1.
- chr5:58,198–12,297,504, 243 genes, copy number 10–17 (broad region; genes not listed).
- chr5:13,144,000–16,941,951, 47 genes, copy number 11: AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, AC016575.2, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1, ZNF622, RETREG1, AC024588.1, AC022113.1, Y_RNA, MYO10, RNA5SP179, RPS26P28, RNU6-660P.
- chr5:20,611,806–34,958,964, 177 genes, copy number 12–18 (within-gene range 7–18) (broad region; genes not listed).
- chr5:36,035,021–37,753,435, 32 genes, copy number 11 (within-gene range 6–11): UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5.
- chr5:37,811,589–37,953,827, 1 gene, copy number 13 (within-gene range 6–13): GDNF-AS1.
- chr5:37,899,363–40,067,200, 34 genes, copy number 12–17: LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56.
- chr5:44,698,431–45,895,970, 12 genes, copy number 14: AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:19,290,319–20,493,714, 19 genes, copy number 18–23: AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P.
- chr6:21,485,896–22,675,493, 14 genes, copy number 27 (within-gene range 4–27): LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2.
- chr6:30,688,047–30,830,659, 13 genes, copy number 17 (within-gene range 7–17): NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P, LINC00243.
- chr6:31,268,749–33,329,286, 194 genes, copy number 12–21 (broad region; genes not listed).
- chr6:34,279,679–35,556,264, 37 genes, copy number 14 (within-gene range 7–14): NUDT3, RPS10-NUDT3, RPS10, PACSIN1, SPDEF, IFITM3P3, ILRUN, RPL7P25, RN7SL200P, AL031577.1, AL451165.2, AL451165.1, AL139100.1, SNRPC, UHRF1BP1, Y_RNA, RNY3P15, TAF11, ANKS1A, HSPE1P11, AL591002.1, AL138721.1, TCP11, SCUBE3, Z97832.2, ZNF76, Z97832.1, DEF6, PPARD, MKRN6P, FANCE, RPL10A, MIR7111, TEAD3, TULP1, AL033519.4, AL033519.3.
- chr6:35,607,628–35,607,934, 1 gene, copy number 14: AL033519.2.
- chr6:35,943,516–38,154,624, 58 genes, copy number 13: SLC26A8, DPRXP2, MAPK14, Z95152.1, MAPK13, Z84485.1, BRPF3, PNPLA1, BNIP5, ETV7, ETV7-AS1, PXT1, KCTD20, RN7SL502P, STK38, RN7SL748P, SRSF3, MIR3925, RNU1-88P, Y_RNA, PANDAR, LAP3P2, CDKN1A, DINOL, RAB44, Z85996.1, CPNE5, Z85996.2, Z85996.3, PPIL1, C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1.
- chr6:38,207,274–38,207,345, 1 gene, copy number 13: AL033518.1.
- chr6:39,048,781–39,115,186, 3 genes, copy number 23: GLP1R, SAYSD1, ANKRD18EP.
- chr6:41,868,622–42,142,620, 10 genes, copy number 15 (within-gene range 7–15): AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132.
- chr6:43,995,723–52,284,881, 121 genes, copy number 13–32 (within-gene range 11–44) (broad region; genes not listed).
- chr6:56,056,590–58,438,364, 33 genes, copy number 9–18: COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1.
- chr13:31,739,526–31,846,539, 2 genes, copy number 10: RXFP2, AL138708.1.
- chr13:50,361,410–50,387,158, 2 genes, copy number 9: RPL34P26, AL158195.1.
- chr13:73,686,089–73,995,056, 1 gene, copy number 9 (within-gene range 7–9): KLF12.
- chr13:73,844,683–74,830,080, 10 genes, copy number 9: AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347, RIOK3P1.
- chr13:75,871,038–75,883,811, 2 genes, copy number 11 (within-gene range 7–11): LMO7DN, LMO7DN-IT1.
- chr13:99,404,684–99,432,702, 2 genes, copy number 10: CCR12P, AL136961.1.
- chr14:18,333,726–20,357,904, 113 genes, copy number 9–15 (broad region; genes not listed).
- chr17:8,729,935–22,706,703, 498 genes, copy number 10–32 (broad region; genes not listed).
- chr17:62,910,021–65,227,703, 103 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 231. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
